Gene-level copy-number profile of tumor specimen TCGA-AA-3811-01A from TCGA case TCGA-AA-3811, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with neuroendocrine differentiation; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 84.6 years (30,893 days).
Specimen TCGA-AA-3811-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.56459c9a-5c25-46dd-a8ee-663e38c4aa8b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3811-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/03db51dc-4803-4ccc-a145-ea758ae68a67

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,285; copy number 2: 6,057; copy number 3: 38,644; copy number 4: 11,380; copy number 5: 2,334; copy number 6: 75; copy number 15: 9; copy number 22: 15; copy number 24: 21.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 45 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,185,071–55,713,252, 30 genes, copy number 15–24 (within-gene range 4–24): AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P.
- chr7:56,163,145–56,467,771, 15 genes, copy number 22 (within-gene range 4–22): IFITM3P4, AC006970.1, AC006970.2, CCNJP1, AC073136.1, AC073136.2, AC093392.1, RNU6-1335P, SEPTIN14P24, CICP8, AC093392.2, RNU6-1052P, AC092423.1, AC092447.7, AC092447.10.

Autosomal genes at a single copy (total copy number 1): 1,285. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
